TCGA case TCGA-G4-6307 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/568dbda7-88b5-4330-881f-dc5d6c7ce4ae

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 37 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 37.4 years (13,648 days); Year of diagnosis: 2007; AJCC staging edition: 2nd; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,674 days (4.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 17; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 47 days; Days to treatment end: 229 days; Number of cycles: 12; Treatment dose: 8,640 mg; Prescribed dose: 720; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 47 days; Days to treatment end: 187 days; Number of cycles: 8; Treatment dose: 1,056 mg; Prescribed dose: 153; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,485 days (4.1 years); Disease response: Tumor Free.
- Days to follow up: 1,674 days (4.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 10.2 ng/mL.
- MLH1 (IHC): Normal.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Normal.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 71 kg; Height: 166 cm; BMI: 25.8.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G4-6307-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-G4-6307-01A-01-BS1: Section location: Bottom; Percent tumor cells: 78; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 12.
  Slide TCGA-G4-6307-01A-01-TS1: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 12.
- Sample TCGA-G4-6307-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G4-6307-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Weight kg at diagnosis: 71 kg; Height cm at diagnosis: 166 cm; Lymph nodes examined: Yes; CEA level pretreatment: 10.2; Lymphovascular invasion indicator: Yes; Microsatellite instability: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; Colon polyps at procurement indicator: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,674 days; disease-specific survival: no event (censored), 1,674 days; progression-free interval: no event (censored), 1,674 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G4-6307-01A-11D-1717-01): tumor purity 0.7, ploidy 3.48, whole-genome doublings 1.
